Somatic mutation profile of tumor specimen TCGA-WE-AA9Y-06A (aliquot TCGA-WE-AA9Y-06A-12D-A38G-08) from TCGA case TCGA-WE-AA9Y, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Superficial spreading melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 38.0 years (13,884 days).
Specimen TCGA-WE-AA9Y-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b75ef91-348b-41db-ab7f-79e0b454dc2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-AA9Y-10A (Blood Derived Normal), aliquot TCGA-WE-AA9Y-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5267932-1eec-49fb-8a49-fff8f2874cd8

The open-access MAF lists 80 somatic variants for this specimen: 50 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 27, Splice Site 2, Nonsense Mutation 2, 5'Flank 1, 3'Flank 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.133C>T p.R45* (on ENST00000399959; = p.R46* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as rs1569234653, CM158020, COSV101302319; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.851); catalogued as COSV52628786; called by muse, mutect2
- AASS | c.904T>A p.Y302N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100741618; called by muse, mutect2, varscan2
- ADAMTS18 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.524); catalogued as rs1203049262, COSV99270902; called by muse, mutect2, varscan2
- ANKRD30A | c.3136G>A p.E1046K (on ENST00000611781; = p.E990K on NM_052997.2) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV64623179; called by muse, mutect2, varscan2
- AVPR1B | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1553289701, COSV100899285; called by mutect2, varscan2
- C1QL1 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs746793614, COSV99492656; called by muse, mutect2
- C1orf131 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100009458; called by muse, mutect2, varscan2
- C2CD3 | c.5771A>T p.E1924V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100486146; called by muse, mutect2, varscan2
- CACNG1 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.02); catalogued as rs747450818, COSV99871577; called by muse, mutect2, varscan2
- CD200R1L | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.162); catalogued as COSV101236535; called by muse, mutect2, varscan2
- CRYBG1 | c.6257G>A p.R2086K | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as COSV100954358; called by muse, mutect2
- DACH1 | c.1984G>A p.E662K (on ENST00000619232 / NM_001366712.1; = p.E408K on NM_004392.6) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57506585; called by muse, mutect2, varscan2
- DACT1 | c.1534A>G p.K512E | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.799); catalogued as COSV100241517; called by muse, mutect2
- DMGDH | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs1200335238, COSV99668328; called by muse, mutect2, varscan2
- DSCAM | c.4178C>T p.S1393F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV68025204; called by muse, mutect2
- DYSF | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50336102, COSV99243630; called by muse, mutect2, varscan2
- EAF1 | c.104-1G>A p.X35_splice | Splice Site (SNP) | VAF 6/38 reads (16%) | catalogued as COSV101084960; called by muse, mutect2
- FAM13C | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as COSV99512885; called by muse, mutect2, varscan2
- GLMP | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55294506, COSV55295808; called by muse, varscan2
- HMCN1 | c.2948T>G p.I983S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54886820, COSV99622935; called by muse, mutect2, varscan2
- HMGXB4 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as rs1282870567, COSV99329863; called by muse, mutect2, varscan2
- HS6ST3 | c.708G>A p.R236= | Splice Region (SNP) | VAF 3/27 reads (11%) | catalogued as COSV65003096; called by muse, mutect2
- MAP3K9 | c.2122G>T p.D708Y (on ENST00000554752 / NM_001284230.1; = p.D722Y on NM_033141.4) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV101173423; called by muse, mutect2, varscan2
- MNDA | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.192); catalogued as COSV63741297; called by muse, mutect2, varscan2
- MYBL2 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs201977983, COSV53834120; called by muse, mutect2, varscan2
- NDC80 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as rs866639078, COSV99859321; called by muse, mutect2, varscan2
- NELL1 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as COSV54296468, COSV54333818; called by muse, mutect2
- NLRP10 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.411); catalogued as COSV60778718, COSV60779844; called by muse, mutect2, varscan2
- OAZ3 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100162281; called by muse, mutect2, varscan2
- PAK5 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV62032087; called by muse, mutect2, varscan2
- PCSK1 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); catalogued as COSV60736693; called by muse, mutect2, varscan2
- PIK3C2A | c.2728C>T p.P910S | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99790104; called by muse, mutect2, varscan2
- PKP1 | c.1147T>G p.F383V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV99824795; called by muse, mutect2
- PTK2B | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57751024; called by muse, mutect2, varscan2
- RELN | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100632029; called by muse, mutect2, varscan2
- RFX6 | c.2068C>A p.P690T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.074); catalogued as COSV100263063; called by muse, mutect2, varscan2
- RFX6 | c.2069C>T p.P690L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); catalogued as COSV100263064; called by muse, mutect2, varscan2
- RIMS2 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101344039; called by muse, mutect2, varscan2
- ROS1 | c.5057G>A p.R1686K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.174); catalogued as COSV100876137; called by mutect2, varscan2
- SH3RF2 | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.228); catalogued as COSV100767552; called by muse, mutect2
- SLC27A1 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs149049260, COSV99393628; called by muse, mutect2, varscan2
- SLF1 | c.3065C>A p.P1022Q | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99475504; called by muse, mutect2, varscan2
- SPHKAP | c.3776C>T p.S1259F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100763610, COSV60876699; called by muse, mutect2, varscan2
- SPTBN4 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100149770; called by muse, mutect2
- STK31 | c.2149-1G>A p.X717_splice | Splice Site (SNP) | VAF 23/78 reads (29%) | catalogued as COSV100669050, COSV63455391; called by muse, mutect2, varscan2
- TDRD5 | c.1270C>A p.P424T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.443); catalogued as COSV99675270; called by mutect2, varscan2
- TDRD5 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.122); catalogued as COSV99675273; called by muse, mutect2, varscan2
- ZAN | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs911748674, COSV100768998; called by muse, mutect2, varscan2
- ZFHX3 | c.3203T>A p.L1068Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99194986; called by muse, mutect2, varscan2
- AARS1 | c.2154T>C p.T718= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV99933137; called by muse, mutect2
- AASS | c.903C>T p.P301= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100741619; called by muse, mutect2, varscan2
- ADCY8 | c.1902G>A p.G634= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as COSV53908811; called by muse, mutect2
- ADGRG7 | c.1671G>A p.R557= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV99840427; called by muse, mutect2, varscan2
- CAPRIN1 | c.1968C>T p.F656= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100403462; called by mutect2, varscan2
- CAPS2 | c.1086T>G p.L362= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100157237; called by muse, mutect2
- CCHCR1 | c.522G>T p.L174= | Silent (SNP) | VAF 40/323 reads (12%) | catalogued as COSV100883807; called by muse, mutect2, varscan2
- DOCK1 | c.2247C>T p.I749= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1268220824, COSV54729357, COSV99726382; called by muse, mutect2, varscan2
- GRIN2A | c.3444G>A p.P1148= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs1192386958, COSV58024912, COSV58027288; called by muse, mutect2, varscan2
- KSR2 | c.840G>A p.R280= | Silent (SNP) | VAF 21/185 reads (11%) | catalogued as COSV60400127; called by muse, mutect2, varscan2
- MMP11 | c.546C>T p.F182= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99302985; called by muse, mutect2, varscan2
- NBPF3 | c.42C>T p.L14= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100558324; called by muse, mutect2, varscan2
- NLRP1 | c.1546C>T p.L516= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV99332770; called by muse, mutect2, varscan2
- OR5H6 | c.357C>T p.S119= (on ENST00000642105; = p.S103= on NM_001005479.2) | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as COSV101051737; called by mutect2, varscan2
- PCDHA2 | c.1599C>T p.F533= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as rs201395161; called by muse, mutect2
- PLEKHG4B | c.1086C>T p.F362= (on ENST00000283426; = p.F718= on NM_052909.5) | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV52048191; called by muse, mutect2
- PRSS37 | c.471G>A p.V157= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100633773; called by muse, mutect2, varscan2
- PTHLH | c.201C>T p.I67= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as rs1190307939, COSV99570679; called by muse, mutect2, varscan2
- RFC1 | c.1612T>C p.L538= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as COSV100567384; called by muse, mutect2, varscan2
- RTCB | c.744C>T p.I248= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs772523212, COSV53277443; called by muse, mutect2, varscan2
- RTN3 | c.2607C>T p.S869= (on ENST00000377819 / NM_001265589.2; = p.S73= on NM_006054.4) | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100379792; called by muse, mutect2, varscan2
- SLC38A4 | c.156C>T p.F52= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV56967391; called by muse, mutect2, varscan2
- SPTBN4 | c.315G>A p.E105= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV100149776; called by muse, mutect2
- SYNPO2 | c.3192A>G p.S1064= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100204660; called by mutect2, varscan2
- TCF4 | c.1731C>T p.V577= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100608966; called by muse, mutect2, varscan2
- TMEM161A | c.1149C>T p.I383= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV99365318; called by muse, mutect2, varscan2
- ZKSCAN1 | c.1338C>T p.S446= | Silent (SNP) | VAF 32/158 reads (20%) | catalogued as COSV100164065; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446119 G>A | 3'Flank (SNP) | VAF 15/87 reads (17%) | catalogued as rs766646297; called by muse, mutect2, varscan2
- GABRE | c.784+186C>T | Intron (SNP) | VAF 42/107 reads (39%) | catalogued as rs757928550, COSV100944193; called by muse, mutect2, varscan2
- RUNX2 | chr6:45328333 C>T | 5'Flank (SNP) | VAF 7/35 reads (20%) | catalogued as rs79058520, COSV100175974; called by muse, mutect2, varscan2
